Somatic mutation profile of tumor specimen TARGET-30-PASZPI-01A (aliquot TARGET-30-PASZPI-01A-01D) from TARGET case TARGET-30-PASZPI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.8 years (645 days).
Specimen TARGET-30-PASZPI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0910f1f4-de64-4fef-bb40-b571f8245a3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASZPI-10A (Blood Derived Normal), aliquot TARGET-30-PASZPI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c48dfd4b-706c-410c-9450-e5cba4b58a2e

The open-access MAF lists 21 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 19, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.5249G>T p.R1750L (on ENST00000614293; = p.R1720L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55799224; called by muse, mutect2, varscan2
- CMTM5 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.237); catalogued as COSV100198193, COSV59305216; called by muse, mutect2, varscan2
- DOCK8 | c.6235A>C p.K2079Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as COSV66618791; called by muse, mutect2, varscan2
- IL18R1 | c.696C>A p.N232K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs11465644; called by mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCEH1 | c.1221G>T p.E407D (on ENST00000538775; = p.E367D on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56433505; called by muse, mutect2, varscan2
- NCOA6 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.276); catalogued as COSV62862173; called by muse, mutect2
- PCDHGA2 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV54012430; called by muse, mutect2
- PEX11A | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV55583090; called by muse, mutect2, varscan2
- PLXNB1 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs199576492, COSV56487959; called by muse, mutect2, varscan2
- PZP | c.3662C>A p.A1221D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54356778; called by muse, mutect2, varscan2
- RIPOR3 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1199554662, COSV50387865, COSV50404238; called by muse, mutect2
- USP53 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs745652236, COSV56793264; called by muse, mutect2, varscan2
- ABCC11 | c.1581G>T p.L527F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- EARS2 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2
- FBN2 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FH | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by mutect2, varscan2
- LAIR1 | c.360_362del p.K121del | In Frame Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- SART1 | c.372C>A p.N124K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.2038A>T p.T680S (on ENST00000540229 / NM_001371097.1; = p.T619S on NM_001009562.4) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.078); called by muse, mutect2
- TACC2 | c.7767G>A p.A2589= (on ENST00000334433; = p.A667= on NM_006997.4) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs751529875, COSV53281691; called by muse, mutect2
